CCDI case PBBUEW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/2ef034e5-bb1a-49e0-8e6c-d483d667777b

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.6 years (2,769 days).

Biospecimens (3 samples)
- Sample 0DH27I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH28P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH291: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
